Gene-level copy-number profile of tumor specimen TCGA-24-1469-01A from TCGA case TCGA-24-1469, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.0 years (25,937 days).
Specimen TCGA-24-1469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.66ce7bbf-1056-41e4-afb5-2bd052df849e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1469-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/363bb2f0-4bf3-4303-9c36-fbd8faaf8c0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 466; copy number 2: 17,047; copy number 3: 29,050; copy number 4: 6,320; copy number 5: 5,414; copy number 6: 1,066; copy number 7: 342; copy number 8: 55; copy number 9: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1469-01A-01D-0497-01): tumor purity 0.87, ploidy 3.26, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,921,479, 7 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1.
- chr4:181,064,089–181,159,149, 1 gene (within-gene range 0–2): LINC00290.
- chr12:98,645,290–98,735,433, 1 gene (within-gene range 0–3): APAF1.
- chr12:98,794,485–98,794,964, 1 gene: AC008126.1.
- chr14:68,113,706–68,149,908, 3 genes: AL133370.2, AL133370.1, RN7SL706P.
- chr14:102,770,040–103,057,549, 6 genes (within-gene range 0–2): AL132801.1, TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 411 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,565,298–234,760,056, 12 genes, copy number 8: AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672.
- chr3:168,902,194–169,869,935, 21 genes, copy number 8: LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr5:10,225,507–31,329,146, 250 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:50,396,192–54,310,582, 54 genes, copy number 7: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1.
- chr6:106,607,716–107,459,564, 14 genes, copy number 9 (within-gene range 3–9): RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr11:78,015,715–78,582,156, 21 genes, copy number 8: AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 8: AP002768.1.
- chr19:28,883,430–29,015,160, 6 genes, copy number 7 (within-gene range 5–7): LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr20:87,250–1,118,467, 28 genes, copy number 7: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1.
- chr20:64,255,695–64,313,132, 4 genes, copy number 7 (within-gene range 5–7): PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 457. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
